Surgical pathology report (de-identified scan), TCGA case TCGA-09-1674, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1674-01A (Primary Tumor).

[page 1 of 3]
FINAL PATHOLOGIC DIAGNOSIS

- A. Right adnexa, salpingo-oophorectomy:
-Ovary: Serous carcinoma; see comment.
-Fallopian tube: Serosal involvement by serous carcinoma.
B. Left adnexa, salpingo-oophorectomy:
-Ovary: Serous carcinoma; see comment.
-Fallopian tube: No significant pathologic abnormality.
C. Omentum, omentectomy: Serous carcinoma.
D. Omentum, omentectomy: Serous carcinoma.

COMMENT:

The tumor distribution favors a primary origin in bilateral ovaries. The volume of tumor is greater in the right compared to the left.

Ovarian Tumor Synoptic Comment

- **Location of tumor:** Bilateral.
- **Type of tumor:** Serous carcinoma.
- **Grade of tumor:** 3.
- **Size of tumor:** Right ovary: 2.5 cm; left ovary: microscopic.
- **Condition of capsule:** Ruptured.
- **Cut surface:** Solid.
- **Necrosis:** Focal.
- **Lymphatic/vascular invasion:** None.
- **Sites of metastases in pelvis:** None.
- **Pelvic lymph nodes:** None sampled.
- **Sites of metastases in abdomen:** Omentum.
- **Size of largest abdominal metastasis:** Diffuse/confluent sub-centimeter nodules of tumor involving the omentum.
- **Para-aortic lymph nodes:** None sampled.

Page 1 of 3

- **Peritoneal cytology:** Not sampled.
- **Other findings:** None.
- **FIGO stage:** IIIC.
- **AJCC stage:** pT3cNXMX.

Specimen(s) Received

- A: Right tube and ovary (FS)
B: Left tube and ovary (fresh for oncotech)
C: Omentum #1 (fresh)
D: Omentum #2

Intraoperative Diagnosis

FS1 (A) Right ovary and tube, salpingo-oophorectomy: Adenocarcinoma. (Dr.

Clinical History

The patient is a [REDACTED] woman with an adnexal mass and carcinomatosis.

[page 2 of 3]
[REDACTED]

The specimen is received in four parts, each labeled with the patient's name and medical record

number. Parts A is received fresh.

Part A is additionally labeled "right tube and ovary." The specimen consists of a single segment of tan-yellow soft tissue that weighs 10 grams and measures 4.2 x 2.5 x 1.8 cm. In the soft tissue, there is a firm, white, papillary lesion that involves the center of the specimen, extends to the surface and measures 2.5 cm. No normal ovary is identified grossly. Two segments of fallopian tube are identified grossly that have been disrupted and are discontinuous and adherent to the surrounding soft tissue. These segments measures 2.2 x 0.5 and 0.8 x 0.5 cm, respectively. A portion of the papillary lesion is submitted for frozen section diagnosis, with the frozen section remnant submitted in cassette A1. The remainder of the specimen is entirely submitted in cassettes

A2-A8. [REDACTED]

Part B is additionally labeled "left tube and ovary." The specimen consists of a previously opened circular structure that has been disrupted prior to receipt in Pathology. It measures 9 x 8 x 3.9 cm and weighs 84 grams. The cyst wall of the specimen measures from 0.1 cm in thickness to 0.6 cm in thickness. No papillary or large solid areas of growth are identified. No fallopian tube is identified grossly. A portion of the specimen is sent for Oncotech. Representative sections are submitted in cassettes B1-B8. [REDACTED]

Part C is additionally labeled "omentum." The specimen consists of a single segment of unoriented, tan-yellow, adipose tissue that measures 23 x 10 x 4 cm. The specimen is serially sectioned and is most remarkable for innumerable tan-white, firm nodules that litter the entire segment of the omentum and involve both the surface and center of the omentum. The nodules measure from 0.1 to 0.5 cm in dimension. Representative sections are submitted in cassettes C1-C5. [REDACTED]

Part D is received in formalin labeled "omentum #2," and consists of two sheets of soft-to-firm, irregular, bloody, yellow, fatty tissue measuring 17 x 12 x 2.5 cm in aggregate. After initial palpation and initial examination, multiple firm nodules are found scattered about the specimen. The specimen is serially sectioned at 1-cm intervals. Cut sections reveal scattered areas of firm, white-tan tissue.

The scattered firm areas range between 1 to 3 cm in maximum dimension.

Representative sections

are submitted in cassettes D1-D4. [REDACTED]

Diagnosis based on gross and microscopic examinations. Final diagnosis made by

[page 3 of 3]
[REDACTED]

attending
pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file 227c76cf-69e4-4649-a714-37ccea3ab350 (TCGA-09-1674.D8E0DDD2-304D-4F5E-9225-2CD88AE9984E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).